Somatic mutation profile of tumor specimen TCGA-32-4211-01A (aliquot TCGA-32-4211-01A-01D-1353-08) from TCGA case TCGA-32-4211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,748 days).
Specimen TCGA-32-4211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c357ccc6-d115-481a-9e8d-4f3c2ba17d94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-4211-10A (Blood Derived Normal), aliquot TCGA-32-4211-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1990526-90a1-446a-adc8-c0f49db04bd7

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 39, Silent 13, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMT | c.14dup p.S6Kfs*22 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs773988915; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4786C>T p.R1596C (on ENST00000303395 / NM_001202435.3; = p.R1585C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917993, CM071991, COSV57683326; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 64/245 reads (26%) | catalogued as COSV66105924; called by muse, mutect2, varscan2
- ADAMTS20 | c.1919G>C p.R640T | Missense Mutation (SNP) | VAF 458/503 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216702479, COSV67139731; called by muse, varscan2
- ANK2 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs775323997, COSV52150043; called by muse, mutect2, varscan2
- ARMC4 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs866229398, COSV59474356; called by muse, mutect2
- ATP6V0A4 | c.1314C>A p.D438E | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.122); catalogued as COSV59473308; called by muse, mutect2, varscan2
- C7orf57 | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.114); catalogued as rs945836494, COSV62364295; called by muse, mutect2
- CSTA | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs201579531, COSV52611812; called by muse, mutect2, varscan2
- DCTN2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 730/822 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV54059270; called by muse, varscan2
- DNAH2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50020974; called by muse, mutect2, varscan2
- DNTT | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs755818841, COSV64522745; called by muse, mutect2, varscan2
- ENPP4 | c.1058G>C p.G353A | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58088434; called by muse, mutect2, varscan2
- F13A1 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs199564311, COSV53553068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCN1 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104861; called by muse, mutect2, varscan2
- GJA9 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62531870; called by muse, mutect2, varscan2
- GNAT3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.315); catalogued as COSV68070187; called by muse, mutect2, varscan2
- GPM6A | c.276C>G p.F92L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV54535419, COSV54537996; called by muse, mutect2, varscan2
- GPR141 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 116/546 reads (21%) | catalogued as rs1158816682, COSV57731561; called by muse, mutect2, varscan2
- HELZ2 | c.2306G>A p.G769D (on ENST00000467148 / NM_001037335.2; = p.G200D on NM_033405.3) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64409934, COSV64410506; called by muse, mutect2
- HERC1 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1273325351, COSV71248012; called by muse, mutect2, varscan2
- HIBCH | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs765232044, COSV62890960; called by muse, mutect2, varscan2
- IRF4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1356308443, COSV66704614, COSV66705130; called by muse, mutect2, varscan2
- ITPRIP | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV53390838; called by muse, mutect2, varscan2
- JAG2 | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV59313223; called by muse, mutect2
- JARID2 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV59198420; called by muse, mutect2, varscan2
- KRT9 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs761374587, COSV55851792; called by muse, mutect2, varscan2
- OR1L4 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 119/533 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs370090548; called by muse, mutect2, varscan2
- PITX2 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 37/106 reads (35%) | catalogued as COSV61584903; called by muse, mutect2, varscan2
- POM121 | c.2893G>A p.G965R (on ENST00000434423; = p.G700R on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57522974; called by muse, mutect2, varscan2
- RFPL2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769887594, COSV50709123; called by muse, varscan2
- RYR2 | c.5498T>C p.I1833T | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV63715083; called by muse, mutect2, varscan2
- SLC26A3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs745637222, COSV60641592; called by muse, mutect2
- SMCHD1 | c.4298G>A p.C1433Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.986); catalogued as COSV55268713; called by muse, mutect2, varscan2
- SYT16 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs759664973, COSV70858924; called by muse, mutect2, varscan2
- TAF1 | c.5231T>G p.M1744R (on ENST00000373790 / NM_138923.4; = p.M1765R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52108741; called by muse, mutect2, varscan2
- TLE2 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771368337, COSV53583286; called by muse, mutect2, varscan2
- TPO | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs753687508, COSV61096751; called by muse, mutect2, varscan2
- TRPA1 | c.2492A>T p.Q831L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51556830; called by muse, mutect2
- TTLL2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs34053826, COSV53445817; called by muse, mutect2
- ZNF207 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); catalogued as COSV58302197; called by muse, mutect2, varscan2
- ZNF527 | c.1607G>A p.S536N | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV62229589; called by muse, mutect2, varscan2
- ZNF816 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 143/406 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs755506445, COSV54410611; called by muse, mutect2, varscan2
- PTEN | c.638_640del p.P213del | In Frame Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel*, varscan2
- ABCC10 | c.3921C>T p.D1307= (on ENST00000372530 / NM_001198934.2; = p.D1279= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs144509707; called by muse, mutect2, varscan2
- ARMC3 | c.114A>G p.E38= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs1471137191, COSV53068040; called by muse, mutect2, varscan2
- COMP | c.1104C>T p.G368= | Silent (SNP) | VAF 21/384 reads (5%) | catalogued as CD982557, COSV55876808; called by muse, mutect2
- CYP7A1 | c.348G>A p.P116= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs752121324, COSV56962730; called by muse, mutect2, varscan2
- FGFRL1 | c.1266G>A p.T422= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs375150331; called by muse, mutect2, varscan2
- NOD2 | c.2988C>T p.T996= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV56055008; called by muse, mutect2
- NRXN3 | c.543C>T p.N181= (on ENST00000557594 / NM_001272020.2; = p.N813= on NM_004796.6) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs755216631, COSV55318638, COSV55336599; called by muse, mutect2, varscan2
- OR2A12 | c.552C>T p.F184= | Silent (SNP) | VAF 101/514 reads (20%) | catalogued as rs565722500, COSV68821111, COSV99065255; called by muse, mutect2, varscan2
- PIP4K2B | c.51C>T p.S17= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SLC28A2 | c.606G>A p.V202= | Silent (SNP) | VAF 76/160 reads (48%) | catalogued as COSV61663467; called by muse, mutect2, varscan2
- USH2A | c.12429G>A p.S4143= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs766310214, COSV56337485; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF229 | c.1497T>C p.S499= | Silent (SNP) | VAF 70/295 reads (24%) | catalogued as COSV52160301; called by muse, mutect2, varscan2
- ZNF623 | c.1233G>A p.A411= | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as rs530640705, COSV71697110; called by muse, mutect2, varscan2
